Somatic mutation profile of tumor specimen 0DDLPN from CCDI case PBBNKV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.8 years (2,127 days).
Specimen 0DDLPN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 591ee18a-7117-4c41-9e91-505eaadb268f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDLPC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f46f4ba-b242-48d9-b0bf-f76138426503

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 6, Intron 2, 3'Flank 1, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 276/442 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13975G>A p.V4659M | Missense Mutation (SNP) | VAF 442/1118 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs369296047, COSV68951320; called by muse, mutect2, varscan2
- ANO9 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 145/231 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.261); catalogued as rs757430374, COSV60449455; called by muse, mutect2, varscan2
- CCR3 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 234/701 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.024); catalogued as rs56114788, COSV62461891, COSV62463816; called by muse, mutect2, varscan2
- MYO1D | c.2044C>T p.R682* | Nonsense Mutation (SNP) | VAF 368/1418 reads (26%) | catalogued as rs760757171, COSV59011913, COSV59020833; called by muse, mutect2, varscan2
- NF1 | c.403del p.R135Gfs*30 | Frame Shift Del (DEL) | VAF 390/494 reads (79%) | catalogued as COSV62192249, COSV62192915; called by mutect2, varscan2
- PARM1 | c.529C>A p.H177N | Missense Mutation (SNP) | VAF 314/787 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1023009931; called by muse, mutect2, varscan2
- RASGRP1 | c.1809G>C p.E603D | Missense Mutation (SNP) | VAF 463/1054 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.079); catalogued as COSV60363553; called by muse, mutect2, varscan2
- CCL20 | c.87C>A p.N29K | Missense Mutation (SNP) | VAF 316/984 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by mutect2, varscan2
- DAD1 | c.36C>G p.F12L | Missense Mutation (SNP) | VAF 245/692 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SUZ12 | c.1437+3_1437+6del p.X479_splice | Splice Site (DEL) | VAF 188/245 reads (77%) | called by mutect2, varscan2
- TRAPPC3L | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 508/1312 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ASPN | c.534T>C p.I178= | Silent (SNP) | VAF 479/1783 reads (27%) | called by muse, varscan2
- CHAT | c.1656C>G p.P552= | Silent (SNP) | VAF 294/898 reads (33%) | called by muse, mutect2, varscan2
- IL16 | c.885C>T p.L295= | Silent (SNP) | VAF 169/527 reads (32%) | catalogued as rs1194576405; called by muse, mutect2, varscan2
- ITGA1 | c.3045T>A p.P1015= | Silent (SNP) | VAF 475/1270 reads (37%) | called by muse, mutect2, varscan2
- THOP1 | c.1875G>A p.T625= | Silent (SNP) | VAF 426/1149 reads (37%) | catalogued as rs373236316; called by muse, varscan2
- TMEM192 | c.57A>G p.E19= | Silent (SNP) | VAF 321/887 reads (36%) | called by muse, mutect2, varscan2
- FCN3 | c.232+47C>T | Intron (SNP) | VAF 220/535 reads (41%) | called by muse, mutect2, varscan2
- KRAS | c.450+56G>T | Intron (SNP) | VAF 70/202 reads (35%) | called by muse, mutect2, varscan2
- OR6K3 | chr1:158717144 C>T | 3'Flank (SNP) | VAF 219/483 reads (45%) | catalogued as rs753779664; called by muse, mutect2, varscan2
